Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2E, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2E-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

ICD-O-3

Fibromyxosarcoma 8811/3

Site (Axilla) NOS 0493

9/10/14

Clinical Diagnosis & History:

Myxofibrosarcoma of right axilla.

Specimens Submitted:

- 1: Level 3 lymph node right axilla (fs)
- 2: Radical resection right axillary sarcoma

DIAGNOSIS:

1. Lymph node, level 3, right axilla; excision:
- Five benign lymph nodes (0/5).
2. Axillary sarcoma, right, radical resection:
- Myxofibrosarcoma, high grade, involving adipose tissue and skeletal muscle.
- Tumor measures 12.5 x 11.6 x 7.2 cm.
- Myxoid changes comprise about 80-85%
- Necrosis is present in 10-20%.
- One benign lymph node (0/1)
- Tumor is seen less than 1mm from lateral (skeletal muscle) and 1mm from axillary margin (adipose tissue). Other margins are negative.
- Negative skin.

Note: Tumor is multinodular and shows both low and high grade areas and the low grade component tracks along septal planes and seen close to above specified margins.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Procedures/Addenda:

Addendum Date Ordered:
Date Complete:

Status: Signed Out

** Continued on next page **

[page 2 of 4]
Date Reported:

Addendum Diagnosis

2. Mass, right axillary, radical resection:

- Additional section of skin shows tumor extension to subcutaneous tissue and dermis.

*** Report Electronically Signed Out ***

Signed out by

Gross Description:

1) The specimen is received fresh for frozen consultation, labeled "Level 3 lymph node" and consists of a red tan fatty tissue fragment measuring 3.5 x 2.1 x 1cm. Five lymph nodes ranging in diameter from 0.5 cm to 1.5cm were identified. All lymph nodes were submitted in 2 cassettes.

Summary of sections:

FSC1_1 frozen section control (3 lymph nodes; 1 large bisected and 2 small inked black)

FSC1_2 Frozen section control (2 Lymph nodes; each bisected, inked black)

2) The specimen is received fresh, labeled "Radical resection right axillary sarcoma", and consists of an irregular adipose tissue, measuring 13.2 x 12.5 x 7.6 cm. A piece of tan skin is covered with one surface, measuring 7.5 x 6.2 cm. Long stitch is designated as lateral margin and inked black; medial margin is inked green. Short stitch is designated as axillary margin and inked orange, white long stitch is designated as thoracic dorsal margin and inked red/orange; white short stitch is designated as latissimus margin and inked yellow; blue short stitch is designated as superficial and inked blue; blue long stitch is designated as skin margin lateral and inked red/black. Inferior margin is uninked. The specimen is serially sectioned and cut surface reveals myxoid, white-yellow mass, measuring 12.5 x 11.6 x 7.2, with focal hemorrhage and necrosis. The representative sections of the margins and tumor are submitted. TPS and photos are taken.

LM-lateral margin

AM-axillary margin

Thor- dorsal - thoracic dorsal margin

Lat-latissimus margin

** Continued on next page **

[page 3 of 4]
SM-superficial margin
IM-inferior margin
Lskin-skin lateral margin
MM-medial margin
IM-inferior margin
T-tumor

Summary of Sections:

Part 1: Level 3 lymph node right axilla (fs)

Blocks	Block Designation	PCs
2	{not entered}	

Part 2: Radical resection right axillary sarcoma

Blocks	Block Designation	PCs
1	AXM 1	
1	IM 1	
1	Lat 1	
1	LM 1	
1	LSkin 1	
1	MM 1	
1	Skin 1	
1	SM 1	
12	T 12	
1	Thor-Dorsal 1	

Special Studies:

Result	Special Stain	Comment
RECUT		
RECUT		
RECUT		

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: Five lymph nodes, negative for metastatic tumor.
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: Five lymph nodes, negative for metastatic

** Continued on next page **

[page 4 of 4]
[REDACTED]

[REDACTED]

tumor.

PERMANENT DIAGNOSIS: Same

** End of Report **

Source: NCI Genomic Data Commons file bc217718-9c5b-4b67-85fd-957c8b4265cd (TCGA-DX-AB2E.A4199783-0563-456B-A2F6-4955EFB5D206.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).